Surgical pathology report (de-identified scan), TCGA case TCGA-DF-A2KU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-DF-A2KU-01A (Primary Tumor).

lw 8/23/11

Sample Type TUMOUR

Sample Preparation

Fresh Frozen

Site of Primary (Event)

Uterine

Site of Tissue

endometrial mass

Year of Sample Collection

Age at Sample Collection (yrs)

Sample Comments

Days to Procedure Date

0

Days to Diagnosis

22

Type of Procedure

Surgical resection

Site of Primary (Histology)

Uterus

Bilateral Disease

NO

Tumour Size (cm)

5.5

Histology

Endometrioid adenocarcinoma, NOS

Grade/Differentiation

III

Pathological T

T1b

Pathological N

NO

Number of Nodes Sampled

0

Number of Nodes Positive

9

Clinical M

N/A

Histology Comments

1CB-0-3

adenocarcinoma, endometrioid, NOS
8380/3

Site: endometrium C54.1

lw 8/23/11

Source: NCI Genomic Data Commons file 7c269b01-c1bc-45dd-9b96-934eb0b23fef (TCGA-DF-A2KU.6F425E9F-E02A-4EFB-A0DE-00BF09D9BB98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).